Somatic mutation profile of tumor specimen C3N-02782-01 (aliquot CPT0205780009) from CPTAC case C3N-02782, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.9 years (17,506 days).
Specimen C3N-02782-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4c10b8e-15dc-46bc-9587-ad9ce12a59b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02782-71 (Blood Derived Normal), aliquot CPT0205800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/813b7970-4cf5-4f46-a654-d8944de75e1f

The open-access MAF lists 77 somatic variants for this specimen: 50 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Intron 5, Frame Shift Del 2, 3'UTR 2, Nonsense Mutation 2, RNA 2, 5'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AICDA | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 235/588 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV57564758; called by muse, mutect2, varscan2
- ART1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs537517512, COSV99167151, COSV99167212; called by muse, mutect2, varscan2
- CDCA4 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142685746; called by muse, mutect2, varscan2
- CDHR5 | c.2071C>T p.R691W (on ENST00000358353 / NM_001171968.2; = p.R697W on NM_021924.5) | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs374885544; called by muse, mutect2, varscan2
- CHAD | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.232); catalogued as rs1429285751, COSV99366213; called by muse, mutect2, varscan2
- CIB3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 114/402 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs547459427, COSV54165558; called by muse, mutect2, varscan2
- CT55 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1194722384, COSV99358886; called by muse, mutect2, varscan2
- EGFR | c.685A>T p.S229C | Missense Mutation (SNP) | VAF 3637/4875 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51827895; called by mutect2, varscan2
- FAM47C | c.959C>A p.P320Q | Missense Mutation (SNP) | VAF 127/365 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs782417277, COSV100793009; called by muse, mutect2, varscan2
- FAT2 | c.10718C>G p.T3573S | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs763267937; called by muse, mutect2, varscan2
- HDAC6 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61927740; called by muse, mutect2, varscan2
- HMCN2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs566362392; called by muse, mutect2, varscan2
- KCNC2 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.772); catalogued as rs773066026, COSV100128363; called by muse, mutect2, varscan2
- KERA | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs751817390, COSV104385648; called by muse, mutect2, varscan2
- KIR3DL1 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 186/498 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.074); catalogued as rs1460616438, COSV58496541; called by muse, mutect2, varscan2
- KRTAP4-16 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.61); catalogued as rs543735212; called by muse, varscan2
- LPA | c.5075G>A p.R1692Q | Missense Mutation (SNP) | VAF 188/402 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV60304580; called by muse, mutect2, varscan2
- MC3R | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 61/848 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs1292518863; called by muse, mutect2
- MMP12 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 133/313 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs373941993; called by muse, mutect2, varscan2
- NTSR1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 149/495 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs550491268, COSV65138398; called by muse, mutect2, varscan2
- OR11G2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs754051687, COSV62132951; called by muse, mutect2, varscan2
- OTC | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as CM003031; called by muse, mutect2, varscan2
- PDZRN3 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs753757339, COSV55196217; called by muse, mutect2, varscan2
- PIK3CG | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs373644334, COSV63252525; called by muse, mutect2, varscan2
- PKHD1 | c.6071C>G p.P2024R | Missense Mutation (SNP) | VAF 150/360 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61878905; called by muse, mutect2, varscan2
- PLCZ1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs146251347, COSV56850620, COSV56856935; called by muse, mutect2, varscan2
- PSMD12 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV62066386; called by muse, mutect2, varscan2
- RTN1 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs1259657087; called by muse, mutect2, varscan2
- RXFP3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs754698803, COSV57504049; called by muse, mutect2, varscan2
- TMEM215 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 104/119 reads (87%) | catalogued as rs770473308; called by muse, mutect2, varscan2
- VPS13C | c.9173G>A p.R3058H (on ENST00000644861 / NM_020821.3; = p.R3015H on NM_017684.5) | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs150364963; called by muse, mutect2, varscan2
- CDK13 | c.1978del p.D660Ifs*72 | Frame Shift Del (DEL) | VAF 41/208 reads (20%) | called by mutect2, pindel, varscan2
- DCAF8L1 | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DDX28 | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DEFB115 | c.58T>G p.L20V | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- HEATR5B | c.2109_2112del p.D704Tfs*86 | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | called by pindel, varscan2
- KRTAP4-8 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 107/467 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- LAMP2 | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHX8 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDCD5 | c.331-1G>C p.X111_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- PLCZ1 | c.1288A>G p.M430V | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- POM121C | c.3170C>T p.T1057I (on ENST00000607367; = p.T815I on NM_001099415.3) | Missense Mutation (SNP) | VAF 60/604 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2
- RBP1 | c.388G>C p.V130L (on ENST00000619087 / NM_001365940.2; = p.V192L on NM_002899.5) | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SGCA | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 193/420 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- SLIT2 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- TBX3 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 184/410 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM1 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- UGT2B28 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNT16 | c.891T>A p.D297E (on ENST00000222462 / NM_057168.2; = p.D287E on NM_016087.2) | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZNF596 | c.1036C>G p.H346D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- BCAS3 | c.1887G>A p.P629= (on ENST00000390652 / NM_001353144.2; = p.P614= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/167 reads (37%) | catalogued as rs966114710; called by muse, mutect2, varscan2
- CLASP1 | c.60A>C p.R20= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV55327468; called by muse, mutect2, varscan2
- DNAJC5B | c.99A>G p.E33= | Silent (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- KLHL31 | c.678G>A p.Q226= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- LAMA5 | c.717G>A p.P239= | Silent (SNP) | VAF 140/456 reads (31%) | catalogued as rs749748477, COSV99441640; called by muse, mutect2, varscan2
- MYH2 | c.924G>A p.T308= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs374415748, COSV55441277; called by muse, mutect2, varscan2
- MYH3 | c.4323C>T p.A1441= | Silent (SNP) | VAF 142/319 reads (45%) | catalogued as rs185355384, COSV56870476; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- NEU2 | c.585C>T p.F195= | Silent (SNP) | VAF 96/208 reads (46%) | catalogued as rs1175197435; called by muse, mutect2, varscan2
- PCDHA13 | c.1683C>T p.N561= | Silent (SNP) | VAF 307/623 reads (49%) | catalogued as rs782324778, COSV56486193; called by muse, mutect2, varscan2
- PCNT | c.1479G>A p.A493= | Silent (SNP) | VAF 145/355 reads (41%) | catalogued as rs199864153, COSV64033766; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SLC22A24 | c.864C>T p.S288= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as rs758802285; called by muse, mutect2, varscan2
- TMEM132D | c.2742C>T p.S914= | Silent (SNP) | VAF 115/272 reads (42%) | catalogued as rs745894276; called by muse, mutect2, varscan2
- TMOD4 | c.270C>T p.G90= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs763432309, COSV54859870; called by muse, mutect2
- TTC22 | c.819C>T p.C273= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs1355890862; called by muse, mutect2, varscan2
- WDR86 | c.336C>T p.S112= | Silent (SNP) | VAF 3445/3800 reads (91%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.165G>A p.A55= | Silent (SNP) | VAF 167/527 reads (32%) | catalogued as rs1333813805, COSV56603370; called by muse, mutect2
- AGR2 | c.139+48A>G | Intron (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- CAPN12 | c.1744+19G>T | Intron (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- CTAGE11P | n.57C>T | RNA (SNP) | VAF 226/542 reads (42%) | called by muse, mutect2, varscan2
- DPH6 | c.312+16150T>G | Intron (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010098 G>A | 5'Flank (SNP) | VAF 56/184 reads (30%) | catalogued as rs574758782; called by muse, mutect2, varscan2
- FANCC | c.996+1515G>A | Intron (SNP) | VAF 94/129 reads (73%) | catalogued as rs777464305; called by muse, mutect2, varscan2
- IL1RN | c.*43C>A | 3'UTR (SNP) | VAF 137/328 reads (42%) | called by muse, mutect2, varscan2
- MIR889 | n.21C>T | RNA (SNP) | VAF 72/170 reads (42%) | catalogued as rs767277956; called by muse, mutect2, varscan2
- NBPF6 | c.-7C>T | 5'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as rs1300332277; called by mutect2, varscan2
- SDHA | c.1794+119dup | Intron (INS) | VAF 85/269 reads (32%) | called by mutect2, pindel, varscan2
- SLC25A13 | c.*73C>T | 3'UTR (SNP) | VAF 72/273 reads (26%) | called by muse, mutect2, varscan2
